Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DB, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DB-01A (Primary Tumor).

Operative Procedure:
Median sternotomy thymectomy

Specimen Received:
Thymus, resection

Final Pathologic Diagnosis:

Thymus, resection:

Thymoma.
WHO histologic classification B2.
The inked soft tissue and serosal margins are free of tumor.
Small amount of normal thymic tissue identified adjacent to tumor.
Three benign lymph nodes (0/3).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received is a single formalin-filled container labeled with the patient's name "thymus." The specimen consists of a 14 x 9 x 3 cm tan, lobulated, irregular fatty tissue. Sectioning reveals a 4.3 x 3.5 x 2.8 cm tan, rubbery, predominantly homogeneous, focally hemorrhagic, well delineated mass which comes to within 0.2 cm from the nearest inked soft tissue margin and 0.5 cm from the tan-pink, smooth, glistening serosa at one aspect. No necrosis is present. There are two tan-pink, rubbery possible lymph nodes identified in the fat, 0.4 cm and 0.6 cm.

Representative sections are submitted as follows:

- #1: Mass to inked soft tissue margin
- #2: Mass to serosa
- #3-5: Random mass
- #6: Two whole possible lymph nodes

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Surgical Pathology Report

Taken: DOB: Gender: F

ICD-0.3
Thymoma, type B2 NOS 8584/1
Site: Mediastinum anterior C38.1
path
Thymus C37.9
J 56/13/14

Source: NCI Genomic Data Commons file 61873fe9-2065-42b9-ac5a-3a8cdc433160 (TCGA-X7-A8DB.DF17D3F8-3E25-4528-A988-C2E2C0771AA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).